Somatic mutation profile of tumor specimen MP2PRT-PASMKE-TMP1-A (aliquot MP2PRT-PASMKE-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASMKE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,273 days).
Specimen MP2PRT-PASMKE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 342e077a-3c62-4296-8700-9c83582033d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMKE-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMKE-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b42c59b-656c-46a7-a415-48b94a45f555

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA1 | c.3658C>T p.R1220W | Missense Mutation (SNP) | VAF 167/433 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751809093; called by muse, mutect2, varscan2
- LRWD1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 290/680 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1158653902, COSV52961135; called by muse, varscan2
- SDR42E1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 21/602 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs981202520, COSV61095060; called by muse, mutect2
- SNX33 | c.1470A>C p.K490N | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57913549; called by muse, mutect2, varscan2
- TLE2 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 151/360 reads (42%) | catalogued as COSV53580596; called by muse, mutect2, varscan2
- ZNF628 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 95/783 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.792); catalogued as rs933933321; called by muse, mutect2, varscan2
- BTBD9 | c.1673A>G p.E558G | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFEMP1 | c.81+1G>A p.X27_splice | Splice Site (SNP) | VAF 133/277 reads (48%) | called by muse, mutect2
- HDAC9 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 128/535 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP40 | c.2450C>G p.T817S | Missense Mutation (SNP) | VAF 135/335 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KCNB2 | c.744C>T p.Y248= | Silent (SNP) | VAF 30/636 reads (5%) | called by muse, mutect2
- SH2B1 | c.2220A>G p.G740= | Silent (SNP) | VAF 270/660 reads (41%) | called by muse, mutect2, varscan2
- UGT3A2 | c.549T>C p.Y183= | Silent (SNP) | VAF 204/480 reads (43%) | catalogued as rs760693903; called by muse, mutect2, varscan2
- AC008505.1 | n.5416del | RNA (DEL) | VAF 54/185 reads (29%) | called by mutect2, pindel, varscan2
